Somatic mutation profile of tumor specimen 0DCOLX from CCDI case PBBMVY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.7 years (2,066 days).
Specimen 0DCOLX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fdb67f8d-d196-4053-a22b-ca16989d4d24.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCOLW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6997793-1d50-4e0a-90f4-52ce502f297c

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TAF3 | c.1238C>T p.S413L | Missense Mutation (SNP) | VAF 22/805 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs905860747, COSV60203962; called by muse, mutect2
- AKAP12 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 110/522 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HSD11B1L | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 22/704 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); called by muse, mutect2
- TRIM15 | c.360C>T p.D120= | Silent (SNP) | VAF 99/566 reads (17%) | catalogued as COSV100938763; called by muse, mutect2, varscan2
